Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A67V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A67V-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:
PAT TYPE:

PAGE #: 2
SEX: F
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

year-old with history of pheochromocytoma, diagnosed in with
hypertension. CT scan positive left adrenal mass, presenting for left
laparoscopic adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "L adrenal" Received fresh in a small container is a 38.5 gram untrimmed
adrenal gland that has been previously bisected, 7.9 x 4.9 x 3.4 cm. The
adrenal has a trimmed weight of 26 grams and measures 4.5 x 3.6 x 3.2 cm. It
is remarkable for a 3.7 x 3.7 x 3.6 cm encapsulated tan-brown hemorrhagic
tumor that appears to be encapsulated. No necrosis is noted.
1A-1D. Tumor to capsule.
1E. Tumor to normal.
1F. Normal adrenal.

PROCEDURE: SPDX

VERIFIED BY:

1. Left adrenal, adrenalectomy: Pheochromocytoma.

I, I the signing staff pathologist, have personally
examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Diagnostic Discrepancy		
Dual/Syncronous Primary Noted		

Source: NCI Genomic Data Commons file d30b343a-2cc7-4daf-b241-1c9d8c257f6d (TCGA-RW-A67V.64C97D00-DADB-44D3-8EFB-928CEE6BF13F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).